Somatic mutation profile of tumor specimen MP2PRT-PAURSE-TMP1-A (aliquot MP2PRT-PAURSE-TMP1-A-1-0-D-A81Z-36) from MP2PRT case MP2PRT-PAURSE, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.0 years (716 days).
Specimen MP2PRT-PAURSE-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f2ea0f05-6944-4c33-a934-a7d44c17cb7d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAURSE-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAURSE-NB1-A-1-0-D-A81Z-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e3591589-6c84-4797-b1ae-229fd3a6f865

The open-access MAF lists 12 somatic variants for this specimen: 6 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 6, Silent 6.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 36/436 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- PTPN11 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 130/405 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); catalogued as rs121918454, CM013417, COSV61005613, COSV61008344, COSV61012146; ClinVar: likely pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- ATP8A2 | c.2659G>A p.V887M | Missense Mutation (SNP) | VAF 13/312 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.1); catalogued as rs1191329945; called by muse, mutect2
- TBC1D32 | c.2951C>A p.S984Y | Missense Mutation (SNP) | VAF 44/222 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.413); catalogued as rs1011686211; called by muse, mutect2, varscan2
- MIPOL1 | c.346C>A p.L116I | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZSCAN20 | c.2756C>T p.A919V | Missense Mutation (SNP) | VAF 35/438 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.026); called by muse, mutect2
- FRK | c.594C>T p.D198= | Silent (SNP) | VAF 116/422 reads (27%) | catalogued as rs773491750, COSV101606639; called by muse, mutect2, varscan2
- HOXC11 | c.789G>A p.L263= | Silent (SNP) | VAF 17/422 reads (4%) | catalogued as COSV54533917; called by muse, mutect2
- NKX1-1 | c.300C>T p.C100= | Silent (SNP) | VAF 27/1007 reads (3%) | called by muse, mutect2
- SBK1 | c.987G>A p.A329= | Silent (SNP) | VAF 174/418 reads (42%) | called by muse, mutect2, varscan2
- SCN7A | c.4185C>T p.A1395= | Silent (SNP) | VAF 105/239 reads (44%) | catalogued as rs754268272; called by muse, mutect2, varscan2
- SLC38A8 | c.1047G>A p.P349= | Silent (SNP) | VAF 242/548 reads (44%) | catalogued as rs556526539, COSV55306323; called by muse, varscan2
